Somatic mutation profile of tumor specimen TCGA-D6-8569-01A (aliquot TCGA-D6-8569-01A-11D-2394-08) from TCGA case TCGA-D6-8569, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 52.6 years (19,212 days).
Specimen TCGA-D6-8569-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69e47e48-aeb0-4b4f-aa77-0d8913cb2f66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D6-8569-10A (Blood Derived Normal), aliquot TCGA-D6-8569-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42f58d2e-d90d-4d82-aa57-462b0dbb10c0

The open-access MAF lists 145 somatic variants for this specimen: 105 protein-altering or splice-affecting, 38 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 38, Splice Site 5, Nonsense Mutation 4, Frame Shift Del 3, Frame Shift Ins 1, In Frame Del 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs104894226, CM053285, COSV54237021, COSV54237051; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LRP2 | c.13139dup p.C4381Mfs*12 | Frame Shift Ins (INS) | VAF 18/54 reads (33%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.829T>G p.C277G | Missense Mutation (SNP) | VAF 15/30 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as rs1064795369, COSV52661564, COSV53188691; called by muse, mutect2, varscan2
- ABCC8 | c.4733G>A p.R1578H | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs143557848; ClinVar: uncertain significance; called by muse, mutect2
- ADAMTS17 | c.2080G>T p.G694W | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99170312; called by muse, mutect2, varscan2
- ADGRB3 | c.3347C>A p.A1116E | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV53234852, COSV99483148; called by muse, mutect2, varscan2
- ANKZF1 | c.1348C>A p.Q450K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99850197; called by muse, mutect2, varscan2
- ARHGAP31 | c.2341C>A p.L781I | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV99956438; called by muse, mutect2, varscan2
- BARD1 | c.2093G>A p.G698D | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as rs1553612188, COSV99637691; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRAP | c.634-2A>G p.X212_splice | Splice Site (SNP) | VAF 21/65 reads (32%) | catalogued as COSV100553922; called by muse, mutect2, varscan2
- CACNA1C | c.250C>A p.Q84K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.93); catalogued as COSV100214449; called by muse, mutect2
- CACNA1E | c.3208G>A p.V1070I | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs767567788, COSV62381574; called by mutect2, varscan2
- CCKAR | c.386C>A p.T129N | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99810037; called by mutect2, varscan2
- CD68 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.163); catalogued as COSV99548649; called by muse, mutect2, varscan2
- CEP192 | c.5378C>A p.S1793Y | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV100380448; called by muse, mutect2, varscan2
- CEP41 | c.1106G>A p.G369D | Missense Mutation (SNP) | VAF 46/288 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as COSV99782506; called by muse, mutect2, varscan2
- CHD9 | c.3383C>G p.T1128S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as COSV99528592; called by muse, mutect2, varscan2
- CHEK2 | c.1244C>T p.S415F (on ENST00000382580 / NM_001005735.2; = p.S372F on NM_007194.4) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147877722, COSV60424376; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHMP2B | c.47A>T p.E16V | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as COSV99773176; called by muse, mutect2, varscan2
- CHST15 | c.182G>C p.R61T | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.366); catalogued as COSV100654869; called by muse, mutect2, varscan2
- CLEC4C | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.054); catalogued as COSV100665324; called by muse, mutect2, varscan2
- CMTR1 | c.977G>A p.G326D | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100990836; called by muse, mutect2, varscan2
- CNKSR2 | c.2439G>T p.Q813H | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV99667114; called by muse, mutect2, varscan2
- COL6A3 | c.7187G>T p.C2396F | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99795920; called by muse, mutect2, varscan2
- CRB2 | c.2500C>T p.P834S | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.168); catalogued as COSV100749501; called by muse, mutect2, varscan2
- CSMD3 | c.4408C>T p.R1470* (on ENST00000297405 / NM_001363185.1; = p.R1366* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | catalogued as COSV52262902; called by muse, mutect2, varscan2
- CXorf66 | c.926C>A p.S309Y | Missense Mutation (SNP) | VAF 54/93 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV100983812, COSV65169783; called by muse, mutect2, varscan2
- DGKK | c.2123A>G p.D708G | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.696); catalogued as COSV101052849; called by muse, mutect2, varscan2
- DMRT3 | c.1289C>T p.T430M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.132); catalogued as rs566570084, COSV99505613; called by muse, mutect2, varscan2
- DPYD | c.287A>T p.D96V | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771573678, COSV100031183; called by muse, mutect2, varscan2
- EBF3 | c.202T>A p.F68I | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100798956; called by muse, mutect2, varscan2
- EPHA7 | c.2572C>T p.P858S | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100994227, COSV65188938; called by muse, mutect2, varscan2
- EPHX1 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV55302145; called by muse, mutect2, varscan2
- ERBB4 | c.3299A>T p.E1100V | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as COSV61533075; called by muse, mutect2, varscan2
- FAM155A | c.646T>G p.W216G | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs1286423651, COSV101026379; called by muse, mutect2, varscan2
- FAM172A | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 16/109 reads (15%) | catalogued as rs1160737756, COSV67934295; called by muse, mutect2, varscan2
- FGFBP2 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99469286; called by muse, mutect2, varscan2
- FLNA | c.2326G>A p.G776S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100774232; called by muse, mutect2, varscan2
- FSTL5 | c.2102C>A p.P701Q | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60181721; called by muse, mutect2, varscan2
- GAK | c.267+2T>C p.X89_splice | Splice Site (SNP) | VAF 15/72 reads (21%) | catalogued as COSV100032980; called by muse, mutect2, varscan2
- GRIK2 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs755777802, COSV59784426; called by muse, mutect2, varscan2
- GTF2E1 | c.248A>G p.D83G | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV99381670; called by muse, mutect2, varscan2
- HEATR1 | c.715A>T p.I239F | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV100857324; called by muse, mutect2, varscan2
- HEMGN | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779943930, COSV52325392; called by muse, mutect2, varscan2
- HOOK3 | c.2014A>G p.M672V | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.613); catalogued as COSV56879346; called by muse, mutect2, varscan2
- INF2 | c.2090A>T p.K697M | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs1256555211, COSV99383399; called by muse, mutect2, varscan2
- KBTBD12 | c.224A>T p.Y75F | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV100675330; called by muse, mutect2, varscan2
- KDM1A | c.1226G>A p.G409D | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100752284; called by muse, mutect2, varscan2
- KLC2 | c.71T>G p.V24G | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100384901; called by muse, mutect2, varscan2
- KRTAP5-1 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 53/225 reads (24%) | catalogued as COSV101192862; called by muse, mutect2, varscan2
- LATS2 | c.2254G>T p.D752Y | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101231435; called by muse, mutect2, varscan2
- LCLAT1 | c.376A>G p.R126G | Missense Mutation (SNP) | VAF 75/218 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100091818; called by muse, mutect2, varscan2
- LRIG2 | c.2204C>T p.P735L | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100742911; called by muse, mutect2, varscan2
- LRRK2 | c.4138A>G p.I1380V | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.82); PolyPhen benign (0.027); catalogued as rs777837414, COSV100108805; called by mutect2, varscan2
- MAP9 | c.212A>G p.K71R | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); catalogued as COSV100250659; called by muse, mutect2
- MED4 | c.632G>T p.R211I | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.99); catalogued as COSV99319838; called by muse, mutect2, varscan2
- MYLK2 | c.1414A>C p.T472P | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101044618; called by muse, mutect2, varscan2
- NDUFA9 | c.964A>G p.M322V | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99865194; called by muse, varscan2
- NPAP1 | c.896G>T p.G299V | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.12); catalogued as COSV100274629; called by muse, mutect2, varscan2
- NPAS4 | c.1427C>G p.T476S | Missense Mutation (SNP) | VAF 53/366 reads (14%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.029); catalogued as COSV100214714; called by muse, mutect2, varscan2
- NPY2R | c.219T>A p.H73Q | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs138139550, COSV100279389; called by muse, mutect2, varscan2
- NSD1 | c.1096G>T p.V366L | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.674); catalogued as COSV100728312; called by muse, mutect2, varscan2
- OBSCN | c.8852G>T p.G2951V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs184062354, COSV99471189; called by muse, mutect2, varscan2
- OR2M3 | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.58); catalogued as COSV101513388; called by muse, mutect2, varscan2
- OR51A4 | c.781G>A p.V261I | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs763198309, COSV66748968; called by muse, mutect2, varscan2
- OR5C1 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372241959; called by muse, mutect2, varscan2
- OR6C68 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV101110005; called by muse, mutect2, varscan2
- OR8H1 | c.735G>C p.L245F | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV100476755, COSV100477442; called by muse, mutect2, varscan2
- PARD3 | c.3368T>C p.M1123T | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs774758431, COSV100630798; called by muse, mutect2, varscan2
- PCDH17 | c.1909G>C p.E637Q | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV100931377; called by muse, mutect2, varscan2
- PCDH9 | c.12G>T p.R4S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.015); catalogued as COSV100117648; called by muse, mutect2, varscan2
- PHF24 | c.579G>T p.L193F | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99645884; called by muse, mutect2, varscan2
- PLCE1 | c.325A>T p.I109L | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs771177637, COSV99593092; called by muse, mutect2, varscan2
- PPAT | c.128+1G>T p.X43_splice | Splice Site (SNP) | VAF 32/97 reads (33%) | catalogued as COSV99946982; called by muse, mutect2, varscan2
- PRAMEF19 | c.1060C>G p.L354V | Missense Mutation (SNP) | VAF 118/416 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs897074487, COSV65819796; called by muse, mutect2, varscan2
- RNF180 | c.737A>T p.Y246F | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV99684302; called by muse, mutect2, varscan2
- ROPN1 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs140868038, COSV51739347; called by muse, mutect2
- S100A7A | c.269G>T p.S90I | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as COSV100241435, COSV61330758; called by muse, mutect2, varscan2
- SEMA3A | c.995+2T>C p.X332_splice | Splice Site (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99544756; called by muse, mutect2, varscan2
- SEPTIN11 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.036); catalogued as rs774260132, COSV53583902; called by muse, mutect2, varscan2
- SLC26A6 | c.1435G>C p.V479L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as rs747817795, COSV100257940; called by mutect2, varscan2
- SPATA4 | c.550G>T p.V184F | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV54590447; called by muse, mutect2, varscan2
- SPHKAP | c.307-2A>T p.X103_splice | Splice Site (SNP) | VAF 20/74 reads (27%) | catalogued as COSV100763607; called by muse, mutect2, varscan2
- SRCAP | c.3068C>G p.P1023R | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV99348987; called by muse, mutect2, varscan2
- SSX2IP | c.311A>T p.N104I | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.447); catalogued as COSV100642426; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3286T>C p.S1096P | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100561374; called by muse, mutect2, varscan2
- THAP3 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV99275380; called by muse, mutect2, varscan2
- THBS4 | c.2026G>A p.V676M | Missense Mutation (SNP) | VAF 71/242 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV63468846; called by muse, mutect2, varscan2
- TMEM117 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56897580; called by muse, mutect2, varscan2
- TMEM242 | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as rs782818794, COSV101275234; called by muse, mutect2, varscan2
- TMEM54 | c.626G>T p.R209L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV100231821; called by muse, mutect2, varscan2
- TNKS | c.3791G>A p.S1264N | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.156); catalogued as COSV100125959; called by muse, mutect2, varscan2
- TPTE | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs759630343; called by muse, mutect2
- TRPC1 | c.956A>C p.K319T (on ENST00000476941 / NM_001251845.2; = p.K285T on NM_003304.4) | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99858115; called by muse, mutect2
- TSHB | c.25A>G p.M9V | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99858909; called by muse, mutect2, varscan2
- UNC13C | c.4620G>T p.M1540I | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.038); catalogued as COSV99510303; called by muse, mutect2, varscan2
- WAPL | c.1469C>T p.P490L | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.111); catalogued as COSV100076393; called by muse, mutect2, varscan2
- WDR17 | c.193C>A p.Q65K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99706549; called by muse, mutect2, varscan2
- ZNF787 | c.350C>T p.T117M | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54418631, COSV54420779; called by muse, mutect2, varscan2
- ZNF804A | c.3124G>T p.D1042Y | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100165918; called by muse, mutect2, varscan2
- FLNA | c.882del p.G295Afs*4 | Frame Shift Del (DEL) | VAF 23/45 reads (51%) | called by mutect2, pindel, varscan2
- LPP | c.1337_1345del p.I446_N448del | In Frame Del (DEL) | VAF 27/97 reads (28%) | called by mutect2, pindel, varscan2
- RLF | c.2439del p.S814Pfs*21 | Frame Shift Del (DEL) | VAF 16/67 reads (24%) | called by mutect2, pindel, varscan2
- SORCS3 | c.2348T>A p.L783H | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.701); called by muse, mutect2
- TAAR1 | c.420_421del p.I140Mfs*7 | Frame Shift Del (DEL) | VAF 19/72 reads (26%) | called by mutect2, pindel, varscan2
- ABHD14A-ACY1 | c.603A>T p.P201= | Silent (SNP) | VAF 31/57 reads (54%) | catalogued as COSV99865169; called by muse, mutect2, varscan2
- ADAM30 | c.840A>G p.K280= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as COSV101023739; called by muse, mutect2, varscan2
- AGK | c.624C>T p.G208= | Silent (SNP) | VAF 52/181 reads (29%) | catalogued as COSV100814506; called by muse, mutect2, varscan2
- ARFIP1 | c.147A>G p.T49= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV100616969; called by muse, mutect2, varscan2
- ARHGEF6 | c.2259G>A p.V753= | Silent (SNP) | VAF 56/75 reads (75%) | catalogued as COSV99166328; called by muse, mutect2, varscan2
- BRSK2 | c.609C>T p.G203= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs768816649, COSV100372207; called by muse, varscan2
- CA3 | c.519G>A p.A173= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs754471970, COSV53409804; called by muse, mutect2
- CLEC1B | c.249T>C p.Y83= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV100045922; called by muse, mutect2, varscan2
- CLEC4D | c.567A>G p.Q189= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100222854; called by muse, mutect2, varscan2
- CPSF6 | c.1368A>G p.K456= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as rs1565648929, COSV99878926; called by muse, mutect2, varscan2
- CRTAC1 | c.453G>A p.K151= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV100084888; called by muse, mutect2, varscan2
- CYP2A13 | c.213T>A p.I71= | Silent (SNP) | VAF 36/72 reads (50%) | catalogued as COSV100386592; called by muse, mutect2, varscan2
- DNAJC6 | c.2040C>A p.A680= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV54774642, COSV99673800; called by muse, mutect2, varscan2
- DPEP2 | c.456G>A p.Q152= | Silent (SNP) | VAF 32/120 reads (27%) | catalogued as rs749483316, COSV99263024; called by muse, mutect2, varscan2
- EMCN | c.711C>T p.S237= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs765467506, COSV56458445; called by muse, mutect2, varscan2
- EPHA7 | c.2832C>T p.F944= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV100993131; called by muse, mutect2, varscan2
- FBXL3 | c.730T>C p.L244= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as COSV100842312; called by muse, mutect2, varscan2
- FRAS1 | c.2511G>T p.L837= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV53650662; called by muse, mutect2, varscan2
- GPT2 | c.1455G>A p.G485= | Silent (SNP) | VAF 35/118 reads (30%) | catalogued as COSV100412744; called by muse, mutect2, varscan2
- H3C2 | c.192G>A p.R64= | Silent (SNP) | VAF 17/141 reads (12%) | catalogued as rs1177773736, COSV52519062, COSV99451251; called by muse, mutect2, varscan2
- HBA2 | c.304C>T p.L102= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV99285337; called by muse, mutect2, varscan2
- INTS5 | c.1290C>T p.T430= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs926831776, COSV57952177; called by muse, mutect2, varscan2
- MMP15 | c.1185C>T p.V395= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99539190; called by muse, mutect2, varscan2
- MYH8 | c.5802C>A p.I1934= | Silent (SNP) | VAF 29/153 reads (19%) | catalogued as COSV101238080, COSV67959650; called by muse, mutect2, varscan2
- NBEA | c.1065T>C p.D355= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as rs771784868, COSV100076031; called by muse, mutect2, varscan2
- NOVA2 | c.438C>T p.I146= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99611122; called by muse, mutect2, varscan2
- OBSCN | c.3627C>T p.S1209= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV99471187; called by muse, mutect2, varscan2
- PARP14 | c.3036A>T p.G1012= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV101506214; called by muse, mutect2, varscan2
- PCDH15 | c.660C>T p.L220= | Silent (SNP) | VAF 26/153 reads (17%) | catalogued as COSV100213771; called by muse, mutect2, varscan2
- PRAMEF8 | c.150A>G p.E50= | Silent (SNP) | VAF 24/159 reads (15%) | called by muse, mutect2, varscan2
- RC3H2 | c.1515G>A p.Q505= | Silent (SNP) | VAF 30/125 reads (24%) | catalogued as COSV100605256; called by muse, mutect2, varscan2
- RNASEH2C | c.219G>A p.V73= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV100383783; called by muse, mutect2, varscan2
- SLC9C2 | c.885C>T p.I295= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs780602044, COSV100876502; called by muse, mutect2, varscan2
- SS18L1 | c.699G>A p.A233= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs753902360, COSV100064334; called by muse, varscan2
- THBS4 | c.2025G>A p.L675= | Silent (SNP) | VAF 74/249 reads (30%) | catalogued as COSV100644170; called by muse, mutect2, varscan2
- TTC37 | c.3624A>G p.Q1208= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100706286; called by muse, mutect2, varscan2
- TTN | c.71295A>G p.P23765= (on ENST00000591111; = p.P16341= on NM_003319.4) | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100590539; called by muse, mutect2, varscan2
- TUBGCP4 | c.426A>G p.Q142= | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as COSV99538652; called by muse, mutect2, varscan2
- EME2 | c.570-69C>G | Intron (SNP) | VAF 7/52 reads (13%) | catalogued as COSV99167616; called by muse, mutect2, varscan2
- PDP1 | c.-79G>A | 5'UTR (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99891820; called by muse, mutect2, varscan2
